Somatic mutation profile of tumor specimen TARGET-30-PATESI-01A (aliquot TARGET-30-PATESI-01A-01D) from TARGET case TARGET-30-PATESI, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.1 years (752 days).
Specimen TARGET-30-PATESI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34676864-77e1-401e-a43f-55772795c469.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATESI-10A (Blood Derived Normal), aliquot TARGET-30-PATESI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/434a66ee-dc37-4835-81e9-142bb825755b

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Frame Shift Del 2, Nonsense Mutation 2, Silent 2, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.7705del p.Q2569Rfs*16 (on ENST00000272895 / NM_173076.3; = p.Q2251Rfs*16 on NM_015657.3) | Frame Shift Del (DEL) | VAF 22/62 reads (35%) | catalogued as COSV99790933; called by mutect2, pindel, varscan2
- FCRL3 | c.669G>T p.Q223H | Missense Mutation (SNP) | VAF 52/90 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV63839001; called by muse, mutect2, varscan2
- FXR2 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51517353; called by muse, mutect2, varscan2
- MS4A2 | c.649del p.R217Vfs*6 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as COSV54011564, COSV54011786; called by mutect2, pindel, varscan2
- SUCO | c.2063C>A p.T688K | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55271730; called by muse, mutect2, varscan2
- USP34 | c.952G>C p.A318P | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV68397410; called by muse, mutect2, varscan2
- ZNF318 | c.745G>T p.G249* | Nonsense Mutation (SNP) | VAF 36/99 reads (36%) | catalogued as COSV58929840; called by muse, mutect2, varscan2
- OPN5 | c.471G>A p.W157* | Nonsense Mutation (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- CX3CL1 | c.309C>T p.F103= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as rs767389618, COSV50055424; called by muse, mutect2, varscan2
- SMARCD3 | c.708C>T p.D236= (on ENST00000262188 / NM_001003801.2; = p.D223= on NM_003078.4) | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs916539173, COSV50388888; called by muse, mutect2, varscan2
- DCHS2 | n.5811T>G | RNA (SNP) | VAF 15/94 reads (16%) | catalogued as COSV61767365; called by muse, mutect2, varscan2
- KIF16B | c.3498+3237C>T | Intron (SNP) | VAF 69/170 reads (41%) | called by muse, mutect2, varscan2
